Somatic mutation profile of tumor specimen TCGA-AO-A1KO-01A (aliquot TCGA-AO-A1KO-01A-31D-A188-09) from TCGA case TCGA-AO-A1KO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.0 years (16,817 days).
Specimen TCGA-AO-A1KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87331cb7-abb6-4445-851f-ddaf9e04739f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A1KO-10A (Blood Derived Normal), aliquot TCGA-AO-A1KO-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9fef882-4ff3-439e-b997-0b572984f3c0

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTMR6 | c.951T>A p.A317= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101110864; called by muse, mutect2
- ZSCAN2 | c.948C>T p.S316= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57571849; called by muse, varscan2
